TCGA case TCGA-GV-A3QH — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: BLN - Cleveland Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/33bc6a7c-9844-41e3-96b3-1e34bb3fedd5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Dead; Days to death: 258 days.

Diagnoses (2)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.0; Tissue or organ of origin: Trigone of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 67.6 years (24,681 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 258 days.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Gemcitabine; Days to treatment start: 135 days; Days to treatment end: 170 days; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Transitional cell carcinoma), site: Bladder, NOS. Age at diagnosis: 67.9 years (24,806 days); Days to diagnosis: 125 days; Prior treatment: Yes.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 125 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Bladder, NOS; Days to recurrence: 125 days.
- Days to follow up: 237 days; Disease response: Tumor Free.
- Days to follow up: 258 days; Disease response: Tumor Free.
- Karnofsky performance status: 90.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 91 kg; Height: 184 cm; BMI: 26.9.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 10; Tobacco smoking quit year: 2007; Age at onset: 53.
- Occupation type: Legal Professionals.

Family history
- Relative with cancer history: yes; Relationship type: Grandfather; Relationship primary diagnosis: Bladder Cancer.
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Kidney Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-GV-A3QH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 120 mg.
  Slide TCGA-GV-A3QH-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 0; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-GV-A3QH-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-GV-A3QH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Occupation current: attorney; Occupation primary: attorney; Occupation primary industry: legal; Tobacco smoking history indicator: 4; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Trigone; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: No.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Stable Disease.
- Drug treatment 1: Pharmaceutical therapy drug name: Cddp; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 258 days; disease-specific survival: no event (censored), 258 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 125 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-GV-A3QH-01A-11D-A21Y-01): tumor purity 0.48, ploidy 5.64, whole-genome doublings 2.
